Gene-level copy-number profile of tumor specimen TCGA-57-1585-01A from TCGA case TCGA-57-1585, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.1 years (20,862 days).
Specimen TCGA-57-1585-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.33185003-e0a6-4c8e-bf25-4623b5c7ef82.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-57-1585-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/98302763-37d2-4d45-9042-e37c96b721ae

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4,697; copy number 2: 16,690; copy number 3: 24,309; copy number 4: 9,188; copy number 5: 3,306; copy number 6: 1,105; copy number 7: 87; copy number 8: 344; copy number 9: 15; copy number 11: 72.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-57-1585-01): tumor purity 0.48, ploidy 6.51, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 518 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:162,497,251–164,899,296, 33 genes, copy number 8 (within-gene range 6–8): UHMK1, UQCRBP2, AL596325.1, UAP1, AL596325.2, DDR2, RN7SL861P, HSD17B7, CCDC190, AL392003.2, AL392003.1, RGS4, RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1, NUF2, AL603841.1, RNA5SP62, RNA5SP63, AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA.
- chr1:233,836,080–240,475,187, 130 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr8:114,791,653–114,791,929, 1 gene, copy number 11: CARS1P2.
- chr8:122,977,026–125,367,120, 68 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:130,595,299–131,432,869, 7 genes, copy number 8: AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72.
- chr8:132,507,962–145,066,685, 279 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,520. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
